Somatic mutation profile of tumor specimen TCGA-06-0645-01A (aliquot TCGA-06-0645-01A-01D-1492-08) from TCGA case TCGA-06-0645, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.0 years (20,449 days).
Specimen TCGA-06-0645-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe949df6-3959-478b-8701-158c1c9be519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0645-10A (Blood Derived Normal), aliquot TCGA-06-0645-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e9f0cd-4bcf-4f78-b4bb-88ec6174295b

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 41, Silent 15, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM22 | c.2084G>A p.S695N | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as COSV55988574; called by muse, mutect2, varscan2
- ADGRE2 | c.2126T>G p.I709S | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV59691815; called by muse, mutect2, varscan2
- ALDH1L2 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV51553230; called by muse, mutect2, varscan2
- ALPK1 | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51582134; called by muse, mutect2, varscan2
- BAZ2A | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV51632004; called by muse, mutect2, varscan2
- CASS4 | c.1640T>C p.L547P | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64385463; called by muse, mutect2, varscan2
- CFAP74 | c.1949C>T p.T650M | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755501705, COSV54564756; called by muse, mutect2, varscan2
- CHRNB4 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as rs748071585, COSV55714792; called by muse, mutect2, varscan2
- COL4A4 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs374356930; called by muse, mutect2, varscan2
- DHX30 | c.2545G>A p.D849N (on ENST00000445061 / NM_138615.3; = p.D810N on NM_014966.3) | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as COSV53135453; called by muse, mutect2, varscan2
- DNASE1L1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1011162917, COSV50010002; called by muse, mutect2
- FGF18 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs748249613, COSV51125352; called by muse, mutect2, varscan2
- FRAS1 | c.5672G>A p.R1891H | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs780066836, COSV53642532; called by muse, mutect2, varscan2
- GPR15 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.052); catalogued as COSV52520066; called by muse, mutect2, varscan2
- GRHL3 | c.31C>T p.R11W (on ENST00000350501 / NM_198174.3; = p.R16W on NM_021180.3) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs202164828, COSV52563840; called by muse, mutect2, varscan2
- IFRD2 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV57112695; called by muse, mutect2, varscan2
- ITGA4 | c.1826A>C p.K609T | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV51998049; called by muse, mutect2, varscan2
- KCNB2 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 60/192 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs764013780, COSV73049004; called by muse, varscan2
- KPRP | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1242733211, COSV100908703, COSV64221042; called by muse, mutect2, varscan2
- MAP4K1 | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67712864; called by muse, mutect2, varscan2
- MUC17 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs761973973, COSV60281736; called by muse, mutect2
- NHLRC2 | c.1982G>A p.S661N | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65174395; called by muse, mutect2, varscan2
- NLRP8 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as rs201462125; called by muse, mutect2, varscan2
- NTRK3 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV58110631; called by muse, mutect2, varscan2
- NYNRIN | c.1300C>A p.P434T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); catalogued as COSV66841231; called by muse, mutect2, varscan2
- ODF4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs147153349, COSV60272108; called by muse, mutect2, varscan2
- OR2L8 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100594211, COSV61725683; called by muse, mutect2, varscan2
- PKHD1L1 | c.7663G>A p.D2555N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV65737711; called by muse, mutect2, varscan2
- PODNL1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.184); catalogued as rs1483316106, COSV54307910; called by muse, mutect2, varscan2
- PRSS48 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs778594353, COSV71613550; called by muse, mutect2, varscan2
- RHBDL3 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as rs1346143008, COSV52184651; called by muse, mutect2, varscan2
- SLC35F5 | c.921C>A p.S307R | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV55516969; called by muse, mutect2, varscan2
- SLC45A4 | c.514G>A p.A172T (on ENST00000517878 / NM_001286646.2; = p.A121T on NM_001080431.2) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772292763, COSV50132816; called by muse, mutect2, varscan2
- SMC3 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV62422109; called by muse, mutect2, varscan2
- SMC3 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as COSV62419024; called by muse, mutect2, varscan2
- TAS1R2 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 104/334 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs528372608, COSV64743684; called by muse, mutect2, varscan2
- TAS2R41 | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs371232991; called by muse, mutect2, varscan2
- TAS2R41 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 22/114 reads (19%) | catalogued as rs755872201, COSV68765664; called by muse, mutect2, varscan2
- TMPRSS15 | c.604T>A p.L202I | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.344); catalogued as COSV53035217; called by muse, mutect2, varscan2
- TRPV4 | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.83); PolyPhen probably damaging (1); catalogued as rs769225216, COSV55680125; called by muse, mutect2, varscan2
- ZFP30 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63622357; called by muse, mutect2, varscan2
- ZNF3 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as COSV52796436; called by muse, mutect2, varscan2
- CPAMD8 | c.1989C>T p.V663= (on ENST00000651564; = p.V616= on NM_015692.5) | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs747096894, COSV52231326; called by muse, mutect2, varscan2
- CPZ | c.600G>A p.T200= (on ENST00000360986 / NM_001014447.3; = p.T189= on NM_003652.3) | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs748472126, COSV59924411, COSV59924563; called by muse, mutect2
- CYLC2 | c.891G>A p.T297= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1292325701, COSV66336210; called by muse, mutect2, varscan2
- DNAH10 | c.5571C>T p.Y1857= (on ENST00000409039; = p.Y1796= on NM_207437.3) | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as rs372145244; called by muse, mutect2, varscan2
- ESR1 | c.936C>T p.A312= | Silent (SNP) | VAF 43/146 reads (29%) | catalogued as rs375030142; ClinVar: likely benign; called by muse, mutect2, varscan2
- GCA | c.141T>C p.Y47= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs760706179, COSV52025120; called by muse, mutect2, varscan2
- LILRA1 | c.987G>A p.S329= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs138767008, COSV52178077; called by muse, mutect2, varscan2
- MAGEB6 | c.609G>A p.A203= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs749588986, COSV66871905; called by muse, mutect2, varscan2
- P2RY2 | c.501C>T p.P167= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100232807, COSV60775428, COSV60776674; called by muse, mutect2, varscan2
- PEAK1 | c.1014A>G p.S338= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV56931131; called by muse, mutect2, varscan2
- PLCXD3 | c.519G>A p.A173= | Silent (SNP) | VAF 44/289 reads (15%) | catalogued as rs377065100, COSV60605164; called by muse, mutect2, varscan2
- PLEK2 | c.147C>A p.G49= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV53604283; called by muse, mutect2, varscan2
- SAGE1 | c.264C>T p.N88= | Silent (SNP) | VAF 55/217 reads (25%) | catalogued as rs1556598882, COSV61011696; called by muse, mutect2, varscan2
- TMEM255A | c.654C>T p.L218= | Silent (SNP) | VAF 60/233 reads (26%) | catalogued as COSV59028103; called by muse, mutect2, varscan2
- VIRMA | c.408A>G p.R136= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV52582298; called by muse, mutect2, varscan2
